Somatic mutation profile of tumor specimen TCGA-21-1076-01A (aliquot TCGA-21-1076-01A-02W-0782-08) from TCGA case TCGA-21-1076, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 54.4 years (19,863 days).
Specimen TCGA-21-1076-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e82da531-b9bf-4b9f-96a6-6a3c6e517da7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1076-11A (Solid Tissue Normal), aliquot TCGA-21-1076-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b20b09bf-52f5-41e6-a283-7990c4fa43a7

The open-access MAF lists 401 somatic variants for this specimen: 298 protein-altering or splice-affecting, 94 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 254, Silent 94, Nonsense Mutation 22, Splice Site 9, Frame Shift Del 8, RNA 5, Splice Region 3, Frame Shift Ins 2, Intron 2, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 79/252 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG4 | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV56644794; called by muse, mutect2, varscan2
- ADAM2 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV55862796; called by muse, mutect2, varscan2
- ADAMTS12 | c.1037C>A p.T346N | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61262000; called by muse, mutect2, varscan2
- ADAMTS16 | c.1119G>A p.M373I | Missense Mutation (SNP) | VAF 56/378 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV56998405; called by muse, mutect2, varscan2
- ADGRE1 | c.2405C>A p.A802D | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV51678438; called by muse, varscan2
- ADGRV1 | c.4505C>T p.P1502L | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67979234, COSV67990460; called by muse, mutect2, varscan2
- ADNP2 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs780534183, COSV51540836; called by muse, mutect2, varscan2
- AFG1L | c.1295T>C p.M432T | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV64556883; called by muse, varscan2
- AKAP14 | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 20/379 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV57630739; called by muse, mutect2
- AKAP4 | c.2458G>T p.G820C | Missense Mutation (SNP) | VAF 155/509 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV62074928; called by muse, mutect2, varscan2
- ALMS1 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.222); catalogued as rs756389027, CM127336, COSV100043165; called by muse, mutect2, varscan2
- AMBP | c.451T>C p.Y151H | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54324679; called by muse, mutect2
- ANXA5 | c.721+1G>T p.X241_splice | Splice Site (SNP) | VAF 22/106 reads (21%) | catalogued as rs113374737, COSV56639560; called by muse, mutect2, varscan2
- APEX2 | c.1386del p.L464Cfs*14 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | catalogued as COSV100237847; called by mutect2, pindel, varscan2
- ASXL1 | c.3343A>G p.S1115G | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV60114370; called by muse, mutect2, varscan2
- ATG7 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753893278, COSV61611102; called by muse, mutect2, varscan2
- BCAN | c.590T>A p.L197H | Missense Mutation (SNP) | VAF 20/341 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.194); catalogued as COSV61258135; called by muse, mutect2
- BCDIN3D | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746116960; called by muse, varscan2
- BCHE | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52259515; called by muse, mutect2, varscan2
- BTK | c.1349+1G>T p.X450_splice | Splice Site (SNP) | VAF 41/313 reads (13%) | catalogued as CS022091, CS971634, COSV58122059; called by muse, mutect2, varscan2
- C14orf39 | c.1501C>A p.Q501K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV58783568; called by muse, mutect2, varscan2
- CACYBP | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 71/393 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV100871610, COSV62881371; called by muse, mutect2, varscan2
- CASS4 | c.1571C>A p.S524Y | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV64387438; called by muse, mutect2, varscan2
- CCDC144A | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 15/131 reads (11%) | catalogued as COSV60700047; called by muse, mutect2, varscan2
- CCSER1 | c.1865G>T p.R622I | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1053213704, COSV61449106; called by muse, mutect2, varscan2
- CD300E | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60791097; called by muse, mutect2, varscan2
- CEACAM20 | c.85G>C p.A29P | Missense Mutation (SNP) | VAF 66/900 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV57602472; called by muse, mutect2
- CEP104 | c.1275G>C p.L425F | Missense Mutation (SNP) | VAF 62/395 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as COSV65517979, COSV65520184; called by muse, mutect2, varscan2
- CERCAM | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.34); catalogued as rs756316111, COSV65711503; called by muse, mutect2
- CHD5 | c.2822C>A p.P941Q | Missense Mutation (SNP) | VAF 10/209 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52418325; called by muse, mutect2
- CHRNA5 | c.294G>T p.W98C | Missense Mutation (SNP) | VAF 103/453 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55139501; called by muse, mutect2, varscan2
- CHST8 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs149663537; called by muse, mutect2, varscan2
- CILP | c.3476G>A p.S1159N | Missense Mutation (SNP) | VAF 43/438 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs776934891, COSV56026142; called by muse, mutect2, varscan2
- CLCN6 | c.265G>T p.V89F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV56743485; called by muse, mutect2, varscan2
- CLDN2 | c.323G>T p.C108F | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV61021035; called by muse, mutect2
- CMIP | c.1709G>A p.G570D (on ENST00000537098 / NM_198390.2; = p.G476D on NM_030629.3) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as COSV67699492; called by muse, mutect2, varscan2
- COL4A2 | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.11); catalogued as COSV99070535; called by muse, varscan2
- CORO2A | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs773618810, COSV59663934; called by muse, mutect2, varscan2
- CPS1 | c.602T>A p.I201N | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV51817268; called by muse, mutect2
- CR1 | c.5362A>G p.T1788A | Missense Mutation (SNP) | VAF 27/314 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV65460450; called by muse, mutect2
- CRABP1 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as rs1265380738, COSV55116080; called by muse, mutect2, varscan2
- CRNKL1 | c.290A>T p.Q97L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55638433; called by muse, mutect2, varscan2
- CRYZ | c.630+1G>T p.X210_splice | Splice Site (SNP) | VAF 8/80 reads (10%) | catalogued as COSV61717647, COSV61718223; called by muse, mutect2, varscan2
- CSMD2 | c.877A>T p.N293Y | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV53935059; called by muse, mutect2, varscan2
- CYBB | c.712G>T p.V238L | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV66085880; called by muse, mutect2
- DBF4 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV55997946; called by muse, mutect2, varscan2
- DEFB116 | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 92/598 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV68722309; called by muse, mutect2
- DGKD | c.2403T>A p.Y801* (on ENST00000264057 / NM_152879.3; = p.Y757* on NM_003648.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 72/313 reads (23%) | catalogued as COSV51070943; called by muse, mutect2, varscan2
- DNAH5 | c.2936A>T p.E979V | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV54239503; called by muse, mutect2, varscan2
- DNAH9 | c.7345G>T p.A2449S | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.122); catalogued as COSV52362377; called by muse, mutect2, varscan2
- DPCD | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64509667; called by muse, mutect2, varscan2
- DPPA5 | c.67C>G p.P23A | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV64875809; called by muse, mutect2, varscan2
- DPYSL4 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as rs748333066, COSV58307708, COSV58308721; called by muse, mutect2, varscan2
- DTNA | c.1343C>A p.S448Y | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV52014921; called by muse, mutect2, varscan2
- EBF1 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 48/274 reads (18%) | catalogued as COSV58187120; called by muse, varscan2
- ECM2 | c.1150A>G p.I384V | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV60742008; called by muse, mutect2, varscan2
- EIF3C | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 104/1075 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV59060731; called by muse, varscan2
- ENAM | c.2608C>T p.Q870* | Nonsense Mutation (SNP) | VAF 36/194 reads (19%) | catalogued as COSV68536568; called by muse, mutect2, varscan2
- ENPP4 | c.1144C>G p.P382A | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV58089571; called by muse, mutect2
- ENTHD1 | c.1077G>T p.Q359H | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57322658, COSV57323545; called by muse, mutect2, varscan2
- EP400 | c.4042G>C p.V1348L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV57779077; called by muse, mutect2, varscan2
- EPHB1 | c.2593C>T p.R865W | Missense Mutation (SNP) | VAF 38/464 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758204492, COSV67653431; called by muse, mutect2
- EPPIN-WFDC6 | c.417A>T p.E139D | Missense Mutation (SNP) | VAF 68/592 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV60549128; called by muse, mutect2, varscan2
- ERCC6L | c.2664G>T p.E888D | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV57819598; called by muse, mutect2
- ERVW-1 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as rs751247098, COSV71259685; called by muse, mutect2, varscan2
- EYA4 | c.990A>T p.G330= (on ENST00000531901 / NM_001301013.1; = p.G324= on NM_004100.5) | Splice Region (SNP) | VAF 60/412 reads (15%) | catalogued as COSV62057109; called by muse, mutect2, varscan2
- FAM120C | c.2963G>A p.G988D | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV60260786; called by muse, mutect2
- FAM199X | c.843C>A p.S281R | Missense Mutation (SNP) | VAF 15/211 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV55434124; called by muse, mutect2
- FCN1 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.223); catalogued as COSV65662673; called by muse, mutect2, varscan2
- FGD3 | c.2119G>T p.A707S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV61598831; called by muse, mutect2, varscan2
- FLG2 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 54/473 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs1343765274, COSV101165979; called by muse, mutect2, varscan2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 14/94 reads (15%) | catalogued as rs752538869; called by mutect2, varscan2
- FRMPD4 | c.3436C>G p.Q1146E | Missense Mutation (SNP) | VAF 50/918 reads (5%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.137); catalogued as COSV66219225; called by muse, mutect2
- FSHR | c.1482G>C p.W494C | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58628920; called by muse, mutect2, varscan2
- GABRA5 | c.427G>C p.A143P | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100164945, COSV59482802; called by muse, mutect2
- GABRR2 | c.926C>A p.T309K | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV68764262, COSV68765679; called by muse, mutect2, varscan2
- GLRA2 | c.176A>T p.D59V | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54344392, COSV99490558; called by muse, mutect2
- GOLGA4 | c.2372G>T p.G791V | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as COSV62712157; called by muse, mutect2, varscan2
- GOLGB1 | c.5318T>C p.L1773P | Missense Mutation (SNP) | VAF 90/932 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV61468219; called by muse, mutect2
- GPM6A | c.151C>A p.L51I | Missense Mutation (SNP) | VAF 28/692 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99704794; called by muse, mutect2
- GRB10 | c.1512C>A p.H504Q (on ENST00000398812; = p.H458Q on NM_001001549.3) | Missense Mutation (SNP) | VAF 48/974 reads (5%) | SIFT tolerated (0.98); PolyPhen benign (0.006); catalogued as COSV60013200; called by muse, mutect2
- GRM3 | c.954C>A p.Y318* | Nonsense Mutation (SNP) | VAF 19/81 reads (23%) | catalogued as COSV64468447, COSV64475846; called by muse, mutect2, varscan2
- GUCY1A1 | c.839C>G p.S280W | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56649234, COSV56653780; called by muse, mutect2, varscan2
- HACE1 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53504811; called by muse, mutect2, varscan2
- HCN4 | c.1217A>T p.H406L | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56085499; called by muse, mutect2
- HEATR5A | c.1574G>A p.G525E | Missense Mutation (SNP) | VAF 109/603 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66343500; called by muse, mutect2, varscan2
- HEATR5B | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 81/297 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs867292377; called by muse, mutect2, varscan2
- HEATR6 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV51747288; called by muse, mutect2, varscan2
- HELZ | c.2475G>T p.Q825H | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62379681; called by muse, mutect2, varscan2
- HIRA | c.494-2A>G p.X165_splice | Splice Site (SNP) | VAF 24/96 reads (25%) | catalogued as COSV54277309; called by muse, varscan2
- HMGXB4 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99329862; called by muse, mutect2
- HOXD1 | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.067); catalogued as rs753497224; called by muse, mutect2, varscan2
- HSD3B1 | c.1051C>A p.Q351K | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV52491476; called by muse, mutect2, varscan2
- HTATSF1 | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 20/122 reads (16%) | catalogued as COSV54479973; called by muse, mutect2, varscan2
- ICAM3 | c.1592C>A p.T531K | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs372536524; called by muse, mutect2, varscan2
- IGBP1 | c.844G>T p.D282Y | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60556434; called by muse, mutect2
- IGHV1OR21-1 | c.217A>G p.S73G | Missense Mutation (SNP) | VAF 24/572 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs777590073; called by muse, mutect2
- IGKV2D-29 | c.179G>T p.W60L | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs1241311912, COSV101534394; called by muse, mutect2, varscan2
- IL13RA1 | c.1065C>G p.I355M | Missense Mutation (SNP) | VAF 103/1082 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV65424348; called by muse, mutect2
- IL13RA2 | c.1139C>G p.T380R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV54566219; called by muse, mutect2, varscan2
- IL22RA2 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 16/143 reads (11%) | catalogued as COSV51664030; called by muse, mutect2
- ITGB1BP2 | c.913C>G p.H305D | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52138949; called by muse, varscan2
- ITIH1 | c.1765C>A p.L589M | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV56256812; called by muse, mutect2, varscan2
- ITIH6 | c.993G>A p.W331* | Nonsense Mutation (SNP) | VAF 283/915 reads (31%) | catalogued as COSV54491402; called by muse, mutect2, varscan2
- ITIH6 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.035); catalogued as COSV54491417; called by muse, mutect2, varscan2
- ITPR2 | c.2939T>C p.I980T | Missense Mutation (SNP) | VAF 107/501 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV67272727; called by muse, mutect2, varscan2
- KANSL1L | c.1349G>A p.C450Y | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV55994414; called by muse, mutect2
- KCND2 | c.507G>C p.Q169H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV58592448; called by muse, mutect2, varscan2
- KIR3DL2 | c.1222C>A p.Q408K | Missense Mutation (SNP) | VAF 28/1114 reads (3%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.91); catalogued as COSV54389205; called by muse, mutect2
- KLK2 | c.52G>T p.V18L | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV57570230; called by muse, mutect2, varscan2
- KRT6C | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as rs752146223; called by mutect2, varscan2
- LAMB1 | c.2458+1G>A p.X820_splice | Splice Site (SNP) | VAF 12/234 reads (5%) | catalogued as COSV55967583; called by muse, mutect2
- LCE1B | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs754061206, COSV63980472; called by muse, mutect2, varscan2
- LGALS9C | c.678G>T p.M226I | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV60196195; called by muse, mutect2, varscan2
- LHCGR | c.1929C>A p.C643* | Nonsense Mutation (SNP) | VAF 55/323 reads (17%) | catalogued as COSV54300283; called by muse, mutect2, varscan2
- LIN7A | c.542G>T p.S181I | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.689); catalogued as COSV54018296; called by muse, mutect2, varscan2
- LRP10 | c.1477C>G p.P493A | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV62078600; called by muse, mutect2
- LRP1B | c.8966A>G p.Y2989C | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV67249362, COSV67263837; called by muse, mutect2, varscan2
- LRRC7 | c.1302G>T p.L434F (on ENST00000651989 / NM_001370785.2; = p.L401F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV50518359; called by muse, mutect2
- MAGEB16 | c.570T>A p.Y190* | Nonsense Mutation (SNP) | VAF 14/133 reads (11%) | catalogued as COSV67874246; called by muse, mutect2, varscan2
- MAGI1 | c.297C>G p.F99L | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58333985, COSV58335219; called by muse, mutect2, varscan2
- MALL | c.146A>G p.H49R | Missense Mutation (SNP) | VAF 26/514 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV55601000; called by muse, mutect2
- MDGA2 | c.2714G>C p.C905S (on ENST00000399232 / NM_001113498.2; = p.C607S on NM_182830.4) | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62103807; called by muse, mutect2, varscan2
- MMADHC | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57574167; called by muse, mutect2, varscan2
- MNDA | c.61C>T p.H21Y | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as COSV63740403, COSV63741562; called by muse, mutect2
- MROH2B | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 65/555 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.64); catalogued as COSV68186910; called by muse, mutect2, varscan2
- MRPL9 | c.203dup p.R69Pfs*13 | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | catalogued as rs748801980; called by pindel, varscan2
- MTERF4 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.306); catalogued as rs1296263615; called by muse, mutect2, varscan2
- MTMR8 | c.1460G>T p.S487I | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as COSV66395160; called by muse, mutect2
- MUC4 | c.13698G>C p.K4566N (on ENST00000463781 / NM_018406.7; = p.K330N on NM_004532.6) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV57791661; called by muse, mutect2, varscan2
- MYBL1 | c.1765G>C p.E589Q | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV72919109; called by muse, mutect2
- MYH4 | c.3112-1G>T p.X1038_splice | Splice Site (SNP) | VAF 54/216 reads (25%) | catalogued as COSV55122485; called by muse, varscan2
- NLGN4X | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV52011478; called by muse, mutect2
- NLRC4 | c.328C>A p.H110N | Missense Mutation (SNP) | VAF 96/252 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1426980819, COSV61593849; called by muse, mutect2, varscan2
- NLRP4 | c.2822T>C p.L941P | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56718663; called by muse, mutect2
- NPPB | c.288C>A p.Y96* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV64687739; called by muse, mutect2, varscan2
- NRDE2 | c.1991A>G p.N664S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV62963968; called by muse, mutect2, varscan2
- NRXN3 | c.1589T>C p.V530A (on ENST00000335750 / NM_001330195.2; = p.V157A on NM_004796.6) | Missense Mutation (SNP) | VAF 44/604 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV59777480; called by muse, mutect2
- NTM | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 93/543 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as COSV66186336; called by muse, mutect2, varscan2
- NTM | c.644T>G p.V215G | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66186359; called by muse, mutect2, varscan2
- NWD1 | c.3653C>G p.T1218S | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as COSV60346699; called by muse, mutect2, varscan2
- OPHN1 | c.2027G>A p.R676K | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.122); catalogued as COSV62784554; called by muse, mutect2, varscan2
- OR11G2 | c.308A>T p.N103I | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62132762; called by muse, mutect2, varscan2
- OR1E1 | c.313C>A p.L105M | Missense Mutation (SNP) | VAF 79/298 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.081); catalogued as COSV59459312; called by muse, mutect2, varscan2
- OR2T29 | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.634); catalogued as COSV60771696; called by muse, mutect2, varscan2
- OR52N5 | c.377T>G p.L126R | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57699166; called by muse, mutect2
- OR5AC2 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62280007; called by mutect2, varscan2
- OR5H1 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 46/389 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100641591, COSV63402924; called by muse, mutect2, varscan2
- OR5H14 | c.84C>A p.F28L | Missense Mutation (SNP) | VAF 78/590 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV71194262, COSV71194264; called by muse, varscan2
- OR5I1 | c.911A>G p.E304G | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV56888134; called by muse, mutect2, varscan2
- OR6K2 | c.913C>A p.H305N | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV62743877; called by muse, mutect2, varscan2
- OSBPL8 | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 43/322 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV53886320; called by muse, mutect2, varscan2
- P2RX2 | c.963C>A p.Y321* (on ENST00000343948 / NM_170683.4; = p.Y249* on NM_012226.5) | Nonsense Mutation (SNP) | VAF 21/266 reads (8%) | catalogued as COSV57685562; called by muse, mutect2
- PAPPA2 | c.1957C>A p.R653S | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs370271956, COSV62778067; called by muse, mutect2
- PCDH11X | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53486739; called by muse, mutect2, varscan2
- PCDH15 | c.2909T>C p.V970A | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.232); catalogued as COSV57352707; called by muse, mutect2
- PCDHA7 | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as rs368032433, COSV65338759; called by muse, mutect2, varscan2
- PFAS | c.1792-1G>A p.X598_splice | Splice Site (SNP) | VAF 12/242 reads (5%) | catalogued as COSV58983617; called by muse, mutect2
- PGRMC1 | c.572C>A p.A191D | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV54293194; called by muse, mutect2
- PKHD1 | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 77/388 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61886768; called by muse, mutect2, varscan2
- PLS3 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 25/398 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV56780629; called by muse, mutect2
- PNLDC1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 60/453 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.715); catalogued as rs1443885037, COSV51705338; called by muse, mutect2, varscan2
- PNLIPRP1 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62612608; called by muse, mutect2, varscan2
- PPP1R3A | c.1721C>A p.T574N | Missense Mutation (SNP) | VAF 57/272 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1471261440, COSV52887436; called by muse, mutect2, varscan2
- PPP4R3A | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.065); catalogued as COSV61505637; called by muse, mutect2, varscan2
- PPP4R4 | c.1365T>G p.D455E | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV58556409; called by muse, mutect2, varscan2
- PREX1 | c.4370G>A p.G1457D | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV64254284; called by muse, mutect2, varscan2
- PRTG | c.2320C>T p.Q774* | Nonsense Mutation (SNP) | VAF 60/274 reads (22%) | catalogued as COSV66839011; called by muse, varscan2
- PSG2 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 301/559 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV61545880; called by muse, mutect2, varscan2
- PTCHD1 | c.722A>T p.Q241L | Missense Mutation (SNP) | VAF 73/1134 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV65061819; called by muse, mutect2
- PTPRN | c.1709G>C p.S570T | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV55350306; called by muse, mutect2
- RASA1 | c.2406G>A p.M802I | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57192907, COSV57198698; called by muse, mutect2
- RCBTB1 | c.1349A>T p.Y450F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51635707; called by muse, mutect2, varscan2
- RELN | c.5332T>C p.C1778R | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59019480; called by muse, mutect2
- RFC4 | c.827G>C p.G276A | Missense Mutation (SNP) | VAF 25/254 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as COSV56217365, COSV56217929; called by muse, mutect2, varscan2
- RINT1 | c.1357A>G p.M453V | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.42); catalogued as rs1184845991, COSV57559511; called by muse, mutect2, varscan2
- RNASE10 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 52/305 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV60518453; called by muse, mutect2, varscan2
- RYR2 | c.6834G>T p.Q2278H | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV63698992; called by muse, mutect2, varscan2
- SAMD9 | c.1744A>G p.I582V | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1388047206, COSV66076704; called by muse, mutect2, varscan2
- SATB2 | c.1210C>A p.P404T | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53488960; called by muse, mutect2
- SCN10A | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV71861609; called by muse, mutect2, varscan2
- SCN1A | c.5632G>T p.E1878* (on ENST00000303395 / NM_001202435.3; = p.E1867* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 39/182 reads (21%) | catalogued as rs148703212, COSV57667838; called by muse, mutect2, varscan2
- SCN3A | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.758); catalogued as COSV51809286; called by muse, mutect2, varscan2
- SDK2 | c.3394G>T p.V1132L | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.475); catalogued as COSV66190552, COSV66191490, COSV66193653; called by muse, mutect2, varscan2
- SFTPA2 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 86/453 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs772763359, COSV64882452, COSV64882733; called by muse, mutect2, varscan2
- SIX4 | c.1010G>C p.G337A | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs745392790, COSV53670685; called by muse, mutect2, varscan2
- SLC4A4 | c.1174G>T p.E392* (on ENST00000264485 / NM_001098484.3; = p.E348* on NM_003759.4) | Nonsense Mutation (SNP) | VAF 18/98 reads (18%) | catalogued as COSV52630880; called by muse, varscan2
- SLTM | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs751738807, COSV51055760; called by muse, mutect2, varscan2
- SMARCA4 | c.2080G>T p.D694Y | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV60802586, COSV60808993; called by muse, mutect2, varscan2
- SMOX | c.980A>T p.H327L | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53866416; called by muse, mutect2, varscan2
- SNAI2 | c.128C>A p.P43Q | Missense Mutation (SNP) | VAF 46/361 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV50079705; called by muse, mutect2, varscan2
- SPAM1 | c.893T>A p.L298H | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs766257029, COSV56145881; called by muse, mutect2, varscan2
- SPAST | c.1351A>G p.R451G | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as CD147727, COSV59515965; called by muse, mutect2, varscan2
- SPATA31E1 | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.647); catalogued as COSV57793540; called by muse, mutect2, varscan2
- SPATA31E1 | c.3917G>T p.R1306M | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57793550; called by muse, mutect2
- SPEG | c.2144G>T p.G715V | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56674945; called by muse, mutect2, varscan2
- SREBF2 | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 28/315 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs776891651; called by muse, mutect2
- STAT4 | c.2002G>C p.D668H | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61831160, COSV61832323; called by muse, mutect2
- STRIP2 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 25/310 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV50806027; called by muse, mutect2
- STYXL2 | c.2543G>T p.R848M | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV54808628; called by muse, mutect2
- STYXL2 | c.2544G>T p.R848S | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54804362, COSV54807711; called by muse, mutect2
- STYXL2 | c.2641G>T p.G881C | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as rs1206660067, COSV54807719; called by muse, mutect2, varscan2
- SYNCRIP | c.845A>C p.K282T | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV62288604; called by muse, mutect2, varscan2
- TBX18 | c.1372G>T p.V458L | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.282); catalogued as COSV63737497; called by muse, mutect2, varscan2
- TFEC | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.574); catalogued as rs896136629, COSV55403841; called by muse, mutect2, varscan2
- TGM4 | c.549+1G>T p.X183_splice | Splice Site (SNP) | VAF 10/35 reads (29%) | catalogued as COSV56095184; called by muse, mutect2, varscan2
- TGM5 | c.1265C>A p.S422Y (on ENST00000220420 / NM_201631.4; = p.S340Y on NM_004245.4) | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV55010889; called by muse, mutect2, varscan2
- TIGD4 | c.1168A>T p.T390S | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV58550224; called by muse, mutect2, varscan2
- TLN1 | c.3610C>T p.P1204S | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318866452, COSV59209658; called by muse, mutect2
- TNC | c.3250G>C p.E1084Q | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.297); catalogued as COSV60787536, COSV60790096; called by muse, mutect2, varscan2
- TNN | c.821C>A p.T274K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53430657, COSV99511878; called by muse, mutect2, varscan2
- TNR | c.3860T>A p.V1287E | Missense Mutation (SNP) | VAF 79/1161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54900305; called by muse, mutect2
- TOX | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63844508, COSV63848528; called by muse, mutect2, varscan2
- TRAF6 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV61923091; called by muse, mutect2, varscan2
- TRAT1 | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV55469702; called by muse, mutect2
- TREM1 | c.292G>T p.V98F | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs565216476, COSV55149105; called by muse, mutect2, varscan2
- TRIM50 | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 132/397 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV60794596; called by muse, mutect2, varscan2
- TRIM58 | c.490G>T p.V164L | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV63571423; called by muse, mutect2
- TSHZ2 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as rs745999760, COSV61590076; called by muse, mutect2, varscan2
- TSHZ3 | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 17/654 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53676746; called by muse, mutect2
- TTN | c.98646C>G p.F32882L (on ENST00000591111; = p.F25458L on NM_003319.4) | Missense Mutation (SNP) | VAF 47/546 reads (9%) | PolyPhen benign (0.033); catalogued as COSV60196235; called by muse, mutect2
- TTN | c.52692G>C p.W17564C (on ENST00000591111; = p.W10140C on NM_003319.4) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | PolyPhen probably damaging (0.999); catalogued as COSV59915622, COSV60196260; called by muse, mutect2, varscan2
- TTN | c.23417C>A p.S7806* (on ENST00000591111; = p.S6879* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/104 reads (12%) | catalogued as COSV60145604, COSV60196313; called by muse, mutect2, varscan2
- TTN | c.15733C>T p.Q5245* (on ENST00000591111; = p.Q4318* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 35/206 reads (17%) | catalogued as COSV60196330; called by muse, mutect2, varscan2
- UBE3A | c.2507G>A p.R836K | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV51668404; called by muse, mutect2, varscan2
- UBE3B | c.1056G>C p.K352N | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV55095804; called by muse, mutect2
- UGT2A3 | c.834G>T p.L278F | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV52361179, COSV99279749; called by muse, mutect2
- UGT2B4 | c.1314T>A p.Y438* | Nonsense Mutation (SNP) | VAF 27/125 reads (22%) | catalogued as rs772218125; called by muse, mutect2, varscan2
- UMPS | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 28/220 reads (13%) | catalogued as COSV51738139; called by muse, mutect2, varscan2
- USH2A | c.14232T>A p.H4744Q | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.462); catalogued as COSV56401308; called by muse, mutect2
- UTRN | c.3142G>A p.D1048N | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV62341445; called by muse, mutect2, varscan2
- UTRN | c.10270+1G>T p.X3424_splice | Splice Site (SNP) | VAF 12/95 reads (13%) | catalogued as COSV62310957; called by muse, mutect2, varscan2
- VSIG10 | c.410C>A p.P137H | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100821280; called by muse, mutect2
- WDR17 | c.2677G>T p.V893F | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV54578703; called by muse, mutect2, varscan2
- XXYLT1 | c.727G>C p.D243H | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV59986112; called by muse, mutect2
- ZBBX | c.952A>G p.M318V | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs1344504797, COSV56795388; called by muse, mutect2, varscan2
- ZC4H2 | c.496C>A p.Q166K | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.103); catalogued as COSV62005000; called by muse, mutect2, varscan2
- ZFPM2 | c.1690C>G p.L564V | Missense Mutation (SNP) | VAF 40/398 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV65874769; called by muse, varscan2
- ZFPM2 | c.2050C>A p.P684T | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65874770; called by muse, mutect2
- ZIM2 | c.929C>G p.T310S | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs762247047, COSV55640436; called by muse, mutect2, varscan2
- ZNF112 | c.40G>A p.A14T (on ENST00000337401 / NM_001083335.2; = p.A8T on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 231/615 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61621237; called by muse, mutect2, varscan2
- ZNF208 | c.2849G>T p.C950F | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68109833; called by muse, mutect2, varscan2
- ZNF222 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 16/482 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV51827625; called by muse, mutect2
- ZNF292 | c.1516G>T p.G506C | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as COSV60543046; called by muse, mutect2
- ZNF383 | c.887A>T p.Q296L | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.303); catalogued as COSV61939616; called by muse, mutect2, varscan2
- ZNF462 | c.4553G>T p.R1518M | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52946005; called by muse, mutect2, varscan2
- ZNF594 | c.1423C>G p.L475V | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV101280329, COSV68385834; called by muse, varscan2
- ZNF804A | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100167703, COSV56448862; called by muse, mutect2, varscan2
- ZNF804B | c.2068G>C p.G690R | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV60827517, COSV60840429; called by muse, mutect2
- ACTA2 | c.568T>A p.Y190N | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- AFF1 | c.1127C>G p.T376R | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- AGPS | c.345del p.R117Gfs*22 | Frame Shift Del (DEL) | VAF 12/112 reads (11%) | called by mutect2, varscan2
- BCDIN3D | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 62/238 reads (26%) | called by muse, varscan2
- CALCOCO2 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2
- CALD1 | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD83 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- CNPY4 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- COL6A3 | c.8481C>A p.Y2827* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- CPT1A | c.696G>A p.V232= | Splice Region (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- CRHBP | c.819G>A p.M273I | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2
- CRYZL1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.035); called by muse, mutect2
- DLC1 | c.4200del p.V1401* (on ENST00000276297 / NM_001348081.2; = p.V964* on NM_006094.5) | Frame Shift Del (DEL) | VAF 18/155 reads (12%) | called by mutect2, pindel, varscan2
- DRD1 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.165); called by mutect2, varscan2
- ELF2 | c.1460_1463del p.V487Efs*6 (on ENST00000379550 / NM_001331036.2; = p.V427Efs*6 on NM_006874.4) | Frame Shift Del (DEL) | VAF 21/135 reads (16%) | called by mutect2, pindel, varscan2
- FBXO32 | c.347_360del p.S116Lfs*38 | Frame Shift Del (DEL) | VAF 45/105 reads (43%) | called by mutect2, pindel, varscan2
- FCER2 | c.302G>A p.R101K | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.045); called by muse, mutect2
- HBEGF | c.350T>G p.I117S | Missense Mutation (SNP) | VAF 78/464 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by mutect2, varscan2
- HTT | c.1303C>A p.L435I | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2
- IGHV4-61 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 36/305 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.533); called by muse, varscan2
- IGKV1D-17 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 69/573 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IL1RN | c.201A>C p.L67F (on ENST00000409930 / NM_173842.3; = p.L49F on NM_000577.5) | Missense Mutation (SNP) | VAF 14/261 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); called by muse, mutect2
- KCNH6 | c.951C>G p.I317M | Missense Mutation (SNP) | VAF 45/371 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- KCNH6 | c.1062C>G p.I354M | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- KLHL23 | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- LILRB4 | c.484C>A p.H162N | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- MROH2B | c.209G>C p.R70T | Missense Mutation (SNP) | VAF 14/380 reads (4%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); called by muse, mutect2
- NF1 | c.5828_5838del p.H1943Rfs*17 (on ENST00000358273 / NM_001042492.3; = p.H1922Rfs*17 on NM_000267.3) | Frame Shift Del (DEL) | VAF 12/103 reads (12%) | called by mutect2, pindel, varscan2
- NOX5 | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 8/220 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.023); called by muse, mutect2
- NT5C | c.188G>A p.S63N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- OSER1 | c.541G>T p.D181Y | Missense Mutation (SNP) | VAF 1620/1839 reads (88%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- PGBD2 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 164/720 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POLR2F | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 69/876 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); called by muse, mutect2
- RBM24 | c.181G>A p.D61N (on ENST00000379052 / NM_001143942.2; = p.D16N on NM_153020.2) | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); called by muse, varscan2
- RIN3 | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- SIRPA | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC16A14 | c.501del p.T168Pfs*7 | Frame Shift Del (DEL) | VAF 16/132 reads (12%) | called by mutect2, varscan2
- SLC7A14 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 46/484 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SYNJ2 | c.3553G>T p.E1185* | Nonsense Mutation (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- TJP3 | c.322G>T p.G108W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); called by mutect2, varscan2
- TRGV4 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- URB2 | c.4380G>A p.V1460= | Splice Region (SNP) | VAF 28/467 reads (6%) | called by muse, mutect2
- WDR33 | c.376A>G p.R126G | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- YJU2 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZCCHC12 | c.1036C>A p.R346S | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.099); called by muse, mutect2
- ZNF254 | c.1235del p.G412Afs*15 | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | called by mutect2, pindel, varscan2
- ZNF263 | c.2029C>T p.H677Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ZNF519 | c.1103G>A p.R368K | Missense Mutation (SNP) | VAF 28/438 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.18); called by muse, mutect2
- AACS | c.1764G>A p.K588= | Silent (SNP) | VAF 42/209 reads (20%) | called by muse, mutect2, varscan2
- ACSM2A | c.282C>T p.A94= (on ENST00000219054; = p.A15= on NM_001308169.2) | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV54587263; called by muse, varscan2
- ADAM18 | c.15C>A p.L5= | Silent (SNP) | VAF 27/369 reads (7%) | catalogued as COSV55851086; called by muse, mutect2
- ADAMTSL1 | c.48G>T p.L16= | Silent (SNP) | VAF 126/318 reads (40%) | catalogued as COSV52820036; called by muse, varscan2
- ADAMTSL1 | c.2727C>T p.I909= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1487116800, COSV65895286; called by muse, mutect2, varscan2
- AGPAT2 | c.282C>T p.I94= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs762040181; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANGEL1 | c.216G>A p.V72= | Silent (SNP) | VAF 45/119 reads (38%) | called by muse, mutect2, varscan2
- ANO2 | c.2322G>A p.V774= (on ENST00000356134 / NM_001278597.3; = p.V778= on NM_001278596.3) | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV59033382; called by muse, mutect2, varscan2
- ASCC2 | c.1470C>T p.C490= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as COSV57075191; called by muse, mutect2, varscan2
- ATP10B | c.3195T>A p.A1065= | Silent (SNP) | VAF 52/272 reads (19%) | catalogued as COSV59158769; called by muse, mutect2, varscan2
- BCHE | c.645A>G p.G215= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV52259505; called by muse, mutect2, varscan2
- BMX | c.75T>C p.N25= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs759407744, COSV59591292, COSV59592342; called by muse, mutect2, varscan2
- CAMKK2 | c.1140A>T p.L380= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV61216288; called by muse, mutect2, varscan2
- CCDC33 | c.408C>T p.P136= | Silent (SNP) | VAF 44/209 reads (21%) | catalogued as COSV100351744, COSV58354904; called by muse, mutect2, varscan2
- CHD7 | c.2133G>A p.K711= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV71112820; called by muse, mutect2
- CNTN6 | c.138C>A p.V46= | Silent (SNP) | VAF 40/218 reads (18%) | catalogued as COSV63180842; called by muse, mutect2, varscan2
- CSMD3 | c.9082T>C p.L3028= (on ENST00000297405 / NM_001363185.1; = p.L2859= on NM_052900.3) | Silent (SNP) | VAF 36/561 reads (6%) | catalogued as COSV52248139; called by muse, mutect2
- DMD | c.1945C>A p.R649= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as CD067532, COSV104385820; called by muse, mutect2
- DPYSL5 | c.402C>T p.I134= | Silent (SNP) | VAF 18/190 reads (9%) | called by muse, varscan2
- DRD1 | c.870C>T p.I290= | Silent (SNP) | VAF 19/57 reads (33%) | called by muse, varscan2
- DSPP | c.1566T>C p.N522= | Silent (SNP) | VAF 28/147 reads (19%) | catalogued as COSV56813326; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1533C>T p.V511= (on ENST00000361735 / NM_015935.5; = p.V425= on NM_014955.3) | Silent (SNP) | VAF 45/361 reads (12%) | catalogued as rs201299640; called by muse, mutect2, varscan2
- EFEMP2 | c.327C>T p.C109= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV57260813; called by mutect2, varscan2
- ERCC4 | c.2613G>A p.K871= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV61313734; called by muse, mutect2
- ESR1 | c.1542C>A p.I514= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV52796769; called by muse, mutect2
- FERD3L | c.207G>T p.V69= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV51763499; called by muse, mutect2, varscan2
- FLNC | c.3477G>T p.R1159= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV57960153; called by muse, mutect2, varscan2
- GABBR1 | c.2034C>T p.Y678= | Silent (SNP) | VAF 24/149 reads (16%) | catalogued as rs758589287, COSV63541979; called by muse, mutect2, varscan2
- GPR4 | c.75C>T p.I25= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as rs1310109711; called by muse, mutect2
- HDC | c.741C>A p.T247= | Silent (SNP) | VAF 18/367 reads (5%) | catalogued as rs965590691, COSV51075051; called by muse, mutect2
- INO80D | c.999A>T p.P333= | Silent (SNP) | VAF 42/235 reads (18%) | catalogued as COSV68959534; called by muse, mutect2, varscan2
- JAK1 | c.144C>T p.L48= | Silent (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- KPNA4 | c.1305A>G p.L435= | Silent (SNP) | VAF 23/126 reads (18%) | catalogued as rs145152566; called by muse, mutect2, varscan2
- LRIT2 | c.1494C>T p.R498= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs140185624; called by mutect2, varscan2
- MAGEE1 | c.2520G>A p.Q840= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV63911195; called by muse, mutect2
- MKRN3 | c.561A>C p.A187= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV58811041; called by muse, mutect2, varscan2
- MOCOS | c.1890G>A p.Q630= | Silent (SNP) | VAF 42/217 reads (19%) | catalogued as COSV54345366; called by muse, mutect2, varscan2
- MUC17 | c.5109C>A p.A1703= | Silent (SNP) | VAF 83/266 reads (31%) | catalogued as COSV60295996, COSV60300063; called by muse, mutect2, varscan2
- NDN | c.354C>T p.I118= | Silent (SNP) | VAF 66/189 reads (35%) | catalogued as rs770036657; called by muse, mutect2, varscan2
- NDUFA7 | c.147C>T p.L49= | Silent (SNP) | VAF 119/173 reads (69%) | called by muse, mutect2, varscan2
- NEO1 | c.3363G>T p.V1121= | Silent (SNP) | VAF 26/466 reads (6%) | called by muse, mutect2
- NLGN3 | c.2067G>A p.G689= (on ENST00000358741 / NM_181303.2; = p.G669= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/145 reads (11%) | catalogued as rs775084398, COSV62444477; called by muse, mutect2, varscan2
- NRXN1 | c.3882G>C p.V1294= | Silent (SNP) | VAF 26/186 reads (14%) | catalogued as COSV60510448, COSV60520176; called by muse, mutect2, varscan2
- NTM | c.504T>C p.T168= | Silent (SNP) | VAF 93/550 reads (17%) | catalogued as rs932768205, COSV66186346, COSV66191564; called by muse, mutect2, varscan2
- NUDT18 | c.825C>A p.T275= | Silent (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- NUP133 | c.621G>A p.K207= | Silent (SNP) | VAF 11/251 reads (4%) | catalogued as COSV54573486; called by muse, mutect2
- NUP160 | c.1827C>T p.C609= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV65855108; called by muse, mutect2
- OR1S2 | c.48A>G p.Q16= | Silent (SNP) | VAF 30/151 reads (20%) | catalogued as rs975870520, COSV100224217, COSV56919919; called by muse, mutect2, varscan2
- OR2L13 | c.261C>A p.G87= | Silent (SNP) | VAF 49/722 reads (7%) | catalogued as COSV63557127; called by muse, mutect2
- OR4Q3 | c.618G>T p.V206= | Silent (SNP) | VAF 25/160 reads (16%) | catalogued as COSV59179530; called by muse, mutect2, varscan2
- OR51D1 | c.366C>A p.A122= | Silent (SNP) | VAF 36/223 reads (16%) | catalogued as COSV62914935; called by muse, mutect2, varscan2
- OR52I1 | c.456C>T p.V152= | Silent (SNP) | VAF 44/297 reads (15%) | catalogued as COSV56169240; called by muse, mutect2, varscan2
- OR5M1 | c.438T>C p.T146= | Silent (SNP) | VAF 34/253 reads (13%) | catalogued as COSV73202279; called by muse, mutect2, varscan2
- OR8B12 | c.46T>C p.L16= | Silent (SNP) | VAF 18/146 reads (12%) | catalogued as COSV60912285; called by muse, mutect2, varscan2
- ORC3 | c.99G>T p.G33= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV57642011; called by muse, mutect2, varscan2
- PAX4 | c.810C>T p.A270= | Silent (SNP) | VAF 72/123 reads (59%) | catalogued as COSV58389992; called by muse, mutect2, varscan2
- PNLIPRP1 | c.441G>T p.V147= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV62612601; called by muse, mutect2, varscan2
- PNN | c.1335G>A p.G445= | Silent (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- PNPLA5 | c.954G>C p.L318= | Silent (SNP) | VAF 16/131 reads (12%) | catalogued as COSV53375561; called by muse, mutect2, varscan2
- PRDM1 | c.2235G>T p.V745= | Silent (SNP) | VAF 36/272 reads (13%) | catalogued as COSV64846016; called by muse, mutect2, varscan2
- PROS1 | c.1857G>T p.L619= | Silent (SNP) | VAF 22/181 reads (12%) | catalogued as COSV101260808; called by muse, mutect2, varscan2
- PTPRJ | c.1335G>C p.P445= | Silent (SNP) | VAF 27/255 reads (11%) | catalogued as COSV69253398; called by muse, mutect2, varscan2
- RDM1 | c.135G>A p.L45= | Silent (SNP) | VAF 31/397 reads (8%) | catalogued as rs1162302763; called by muse, mutect2
- RGS5 | c.105C>T p.D35= | Silent (SNP) | VAF 133/920 reads (14%) | catalogued as COSV58353513; called by muse, mutect2, varscan2
- RHO | c.198G>A p.K66= | Silent (SNP) | VAF 22/314 reads (7%) | called by muse, mutect2
- RYR2 | c.7302C>A p.G2434= | Silent (SNP) | VAF 13/213 reads (6%) | catalogued as COSV63698995; called by muse, mutect2
- SAMD15 | c.924T>G p.T308= | Silent (SNP) | VAF 50/644 reads (8%) | catalogued as COSV53627091; called by muse, mutect2
- SCN11A | c.723C>G p.V241= | Silent (SNP) | VAF 26/611 reads (4%) | catalogued as COSV56574098; called by muse, mutect2
- SCN11A | c.648C>T p.I216= | Silent (SNP) | VAF 18/476 reads (4%) | called by muse, mutect2
- SIRT5 | c.405C>T p.V135= | Silent (SNP) | VAF 44/200 reads (22%) | catalogued as rs760106683, COSV63081117; called by muse, mutect2, varscan2
- SLC25A39 | c.859C>T p.L287= (on ENST00000377095 / NM_001143780.3; = p.L279= on NM_016016.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- SLC25A39 | c.420C>T p.I140= (on ENST00000377095 / NM_001143780.3; = p.I132= on NM_016016.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs1435235899; called by muse, mutect2, varscan2
- SLC38A5 | c.831C>T p.P277= | Silent (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- SLC6A18 | c.654G>T p.L218= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV57252918; called by muse, mutect2, varscan2
- SPTB | c.2508G>A p.Q836= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV67633565; called by muse, mutect2, varscan2
- SRPX | c.582C>G p.P194= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as COSV59440088; called by muse, mutect2
- STAB2 | c.1920C>G p.A640= | Silent (SNP) | VAF 120/368 reads (33%) | catalogued as COSV66342903; called by muse, mutect2, varscan2
- TASP1 | c.879T>C p.C293= | Silent (SNP) | VAF 54/420 reads (13%) | catalogued as COSV61814353; called by muse, mutect2, varscan2
- TEKT3 | c.681G>T p.L227= | Silent (SNP) | VAF 9/160 reads (6%) | catalogued as COSV58628623; called by muse, mutect2
- TICRR | c.1020T>A p.I340= | Silent (SNP) | VAF 30/128 reads (23%) | called by muse, mutect2, varscan2
- TMCC2 | c.1333C>T p.L445= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV58005092; called by muse, mutect2, varscan2
- TRAT1 | c.288C>A p.A96= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as COSV55469713; called by muse, mutect2
- TRAV13-1 | c.111C>T p.S37= | Silent (SNP) | VAF 39/549 reads (7%) | catalogued as rs201830464; called by muse, mutect2
- TRIM58 | c.492G>T p.V164= | Silent (SNP) | VAF 30/176 reads (17%) | called by muse, mutect2
- TTN | c.99306T>C p.Y33102= (on ENST00000591111; = p.Y25678= on NM_003319.4) | Silent (SNP) | VAF 35/305 reads (11%) | catalogued as rs762295035, COSV60196194; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.94986A>G p.L31662= (on ENST00000591111; = p.L24238= on NM_003319.4) | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs878926568; called by muse, mutect2, varscan2
- TTN | c.23937T>A p.S7979= (on ENST00000591111; = p.S7052= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV60196303; called by muse, mutect2, varscan2
- TUBE1 | c.916C>T p.L306= | Silent (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- UNC93A | c.1308G>A p.P436= | Silent (SNP) | VAF 42/336 reads (13%) | catalogued as rs147514798; called by muse, varscan2
- ZC3HC1 | c.1168C>T p.L390= | Silent (SNP) | VAF 111/612 reads (18%) | called by muse, mutect2, varscan2
- ZHX2 | c.639A>G p.E213= | Silent (SNP) | VAF 45/172 reads (26%) | catalogued as COSV58715059; called by muse, mutect2, varscan2
- ZNF385D | c.120T>A p.P40= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV55765449; called by muse, mutect2, varscan2
- ZNF554 | c.321A>T p.S107= | Silent (SNP) | VAF 12/251 reads (5%) | catalogued as COSV57886405; called by muse, mutect2
- ZNF835 | c.798C>T p.I266= | Silent (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- ABI2 | c.1193-5579C>T | Intron (SNP) | VAF 25/115 reads (22%) | catalogued as COSV53689891; called by muse, mutect2, varscan2
- AL133467.6 | chr14:95668356 C>T | 5'Flank (SNP) | VAF 21/128 reads (16%) | called by muse, mutect2, varscan2
- AL590867.2 | n.114G>T | RNA (SNP) | VAF 28/250 reads (11%) | called by muse, mutect2, varscan2
- C3P1 | n.2345C>A | RNA (SNP) | VAF 275/1936 reads (14%) | called by muse, mutect2, varscan2
- FAM74A3 | n.303A>G | RNA (SNP) | VAF 18/623 reads (3%) | called by muse, mutect2
- FCRL2 | c.884-72C>T | Intron (SNP) | VAF 20/299 reads (7%) | called by muse, mutect2
- PNPLA3 | c.*360G>T | 3'UTR (SNP) | VAF 27/149 reads (18%) | catalogued as COSV99337091; called by muse, mutect2, varscan2
- SNORD116-29 | n.5C>T | RNA (SNP) | VAF 23/129 reads (18%) | catalogued as rs974377887; called by muse, mutect2, varscan2
- SUGT1P4-STRA6LP | n.1337G>T | RNA (SNP) | VAF 26/344 reads (8%) | called by muse, mutect2
